Gene-level copy-number profile of tumor specimen TCGA-IW-A3M4-01A from TCGA case TCGA-IW-A3M4, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 48.5 years (17,721 days).
Specimen TCGA-IW-A3M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.98958fb5-a984-4173-8e2a-7c4043bf0faa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IW-A3M4-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3350de6d-8ed1-4077-98df-79be2ceb6f30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 12,013; copy number 2: 46,413; copy number 3: 1,389.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IW-A3M4-01A-11D-A21P-01): tumor purity 0.93, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:110,265,251–110,513,209, 4 genes (within-gene range 0–1): AL161773.1, COL4A2, MIR8073, COL4A2-AS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
